Somatic mutation profile of tumor specimen TCGA-CQ-A4CI-01A (aliquot TCGA-CQ-A4CI-01A-11D-A25Y-08) from TCGA case TCGA-CQ-A4CI, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 73.0 years (26,664 days).
Specimen TCGA-CQ-A4CI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25eb521c-13e7-45bf-b8fb-a81278091870.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4CI-10A (Blood Derived Normal), aliquot TCGA-CQ-A4CI-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb029336-e63d-48b3-94a2-1b96166769a0

The open-access MAF lists 120 somatic variants for this specimen: 89 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 28, Nonsense Mutation 7, Frame Shift Ins 2, Splice Site 2, Intron 1, Frame Shift Del 1, In Frame Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIMP2 | c.129C>G p.H43Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.133); catalogued as COSV99763954; called by muse, varscan2
- ALB | c.1361T>A p.L454Q | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99890951; called by muse, mutect2, varscan2
- AMDHD2 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs770281026, COSV53551772; called by muse, mutect2, varscan2
- ANKRD30A | c.752A>T p.H251L (on ENST00000611781; = p.H195L on NM_052997.2) | Missense Mutation (SNP) | VAF 146/3156 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV100653066; called by muse, mutect2
- ARVCF | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs375865872; called by muse, mutect2, varscan2
- ATP2B2 | c.2657C>A p.A886D (on ENST00000352432; = p.A852D on NM_001683.5) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100659776, COSV59499517; called by muse, mutect2, varscan2
- CACNA1B | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV99495718; called by muse, mutect2, varscan2
- CCDC121 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 138/351 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs987821893, COSV99269930; called by muse, mutect2, varscan2
- CDH8 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100179995; called by muse, mutect2, varscan2
- CEP78 | c.1144C>G p.L382V (on ENST00000424347 / NM_001349840.2; = p.L383V on NM_032171.3) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV99450067; called by muse, mutect2, varscan2
- CFAP61 | c.2176A>G p.K726E | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT tolerated (0.96); PolyPhen benign (0.011); catalogued as COSV99843713; called by muse, mutect2, varscan2
- CNTN2 | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 122/247 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs766016860, COSV100084842, COSV59352620; called by muse, mutect2, varscan2
- CNTNAP4 | c.3256C>G p.Q1086E | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.297); catalogued as COSV100269829, COSV56681500; called by muse, mutect2, varscan2
- COL5A1 | c.3041G>A p.R1014H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs754184016, COSV65677505; called by muse, varscan2
- CPNE4 | c.122T>A p.L41H | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.996); catalogued as COSV101456592; called by muse, mutect2, varscan2
- CR1L | c.1234T>A p.S412T | Missense Mutation (SNP) | VAF 80/92 reads (87%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs1413247490, COSV99686929; called by muse, mutect2, varscan2
- CREBBP | c.4873A>G p.M1625V | Missense Mutation (SNP) | VAF 66/95 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV52114982, COSV52130301; called by muse, mutect2, varscan2
- DHRS9 | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV100513371; called by muse, mutect2, varscan2
- DIP2A | c.2581C>T p.Q861* | Nonsense Mutation (SNP) | VAF 55/89 reads (62%) | catalogued as COSV100595391; called by muse, mutect2, varscan2
- EDEM1 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99849058; called by muse, mutect2, varscan2
- EIF2AK3 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV100303540; called by muse, mutect2, varscan2
- EPHA5 | c.2891C>T p.S964F | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.368); catalogued as COSV56651058, COSV99896979; called by muse, mutect2
- EXOC6B | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV55553424, COSV99723155; called by muse, mutect2, varscan2
- FAM47C | c.2626C>A p.P876T | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated (0.38); PolyPhen benign (0.099); catalogued as COSV100792344; called by muse, mutect2, varscan2
- FAM47C | c.2627C>T p.P876L | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.546); catalogued as rs782528684, COSV100792346; called by muse, mutect2, varscan2
- FANCA | c.3828+2T>A p.X1276_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99234655; called by muse, mutect2, varscan2
- FANCM | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV99950632; called by muse, mutect2, varscan2
- FAT1 | c.4579C>T p.Q1527* | Nonsense Mutation (SNP) | VAF 24/36 reads (67%) | catalogued as COSV71672403; called by muse, mutect2, varscan2
- GMIP | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs374915909; called by muse, mutect2, varscan2
- HIVEP1 | c.7708G>A p.E2570K | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV101044847; called by muse, mutect2, varscan2
- HJURP | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs748409832, COSV64978628; called by muse, mutect2, varscan2
- IBSP | c.130T>C p.Y44H | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99883419; called by muse, mutect2, varscan2
- IFNA17 | c.398C>G p.P133R | Missense Mutation (SNP) | VAF 261/342 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs768677578, COSV101303440; called by muse, mutect2, varscan2
- IGKV1D-8 | c.121G>A p.V41I | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.433); catalogued as rs1230504643; called by muse, mutect2, varscan2
- LDHAL6B | c.764T>C p.I255T | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs1240798065, COSV99894748; called by muse, mutect2, varscan2
- LRRK2 | c.3014G>A p.C1005Y | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.116); catalogued as COSV100109483; called by muse, mutect2, varscan2
- LTBP1 | c.4058T>A p.L1353H (on ENST00000404816 / NM_206943.4; = p.L1027H on NM_000627.4) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99697910; called by muse, mutect2, varscan2
- MAGI2 | c.3014G>A p.R1005H | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs751367419, COSV100833490; called by muse, mutect2, varscan2
- MROH2B | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV101270575, COSV101270679; called by muse, mutect2, varscan2
- MRPS18B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs375661910; called by muse, mutect2, varscan2
- MSANTD4 | c.755T>G p.L252R | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV100108536; called by muse, mutect2, varscan2
- NALCN | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 92/113 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51958031; called by muse, mutect2, varscan2
- NEPRO | c.1478C>A p.T493N | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV99868253; called by muse, mutect2, varscan2
- NOLC1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99531394; called by muse, mutect2, varscan2
- NTAQ1 | c.602G>C p.G201A | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV99073899, COSV99783542; called by muse, mutect2, varscan2
- OR52B2 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101603928; called by muse, mutect2, varscan2
- OR8H1 | c.318G>T p.L106F | Missense Mutation (SNP) | VAF 101/311 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV57295229; called by muse, mutect2, varscan2
- OR8J3 | c.610G>C p.A204P | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100040617; called by muse, mutect2, varscan2
- PLA2G4C | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV100843869; called by muse, mutect2
- PPP1R17 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100566304; called by muse, mutect2, varscan2
- PRDM9 | c.2581G>A p.V861I | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.709); catalogued as rs780084938, COSV99689931; called by muse, mutect2, varscan2
- REV3L | c.1220A>G p.D407G | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100724968; called by muse, mutect2, varscan2
- REV3L | c.1219G>T p.D407Y | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100724972; called by muse, mutect2, varscan2
- RIC1 | c.2365C>T p.L789F | Missense Mutation (SNP) | VAF 179/273 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52611693, COSV99316851; called by muse, mutect2, varscan2
- RPS6KA2 | c.1368G>C p.E456D | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99690362; called by muse, mutect2, varscan2
- RTL3 | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as rs745795742, COSV100329595; called by muse, mutect2, varscan2
- RUFY3 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV99886913; called by muse, mutect2, varscan2
- RUNX1T1 | c.1463G>T p.R488L (on ENST00000265814 / NM_001198628.1; = p.R461L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.621); catalogued as COSV56154710; called by muse, mutect2, varscan2
- SASH1 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.152); catalogued as COSV100820980; called by muse, mutect2, varscan2
- SGTB | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 26/119 reads (22%) | catalogued as rs1421383239, COSV101121577, COSV66817584; called by muse, mutect2, varscan2
- SLC24A1 | c.1154C>A p.A385E | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV99978099; called by muse, mutect2, varscan2
- SLC38A10 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs201582210, COSV55844861; called by muse, mutect2, varscan2
- SLC45A1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as rs749157979, COSV57096638; called by muse, mutect2, varscan2
- SLC9A2 | c.2101G>A p.G701R | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.232); catalogued as rs1421533589, COSV99295951; called by muse, mutect2, varscan2
- SLCO1B1 | c.773G>T p.W258L | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57015671, COSV99918115; called by muse, mutect2, varscan2
- SLITRK1 | c.542A>G p.H181R | Missense Mutation (SNP) | VAF 70/101 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100999830; called by muse, mutect2, varscan2
- SOS1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.788); catalogued as rs886041241, COSV67673938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STYXL2 | c.2861G>A p.W954* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV99608729; called by muse, mutect2, varscan2
- SUN1 | c.1594G>A p.V532M (on ENST00000405266 / NM_001367651.1; = p.V412M on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/294 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs750763397, COSV67452239; called by muse, mutect2, varscan2
- SYNE1 | c.14809A>C p.S4937R (on ENST00000367255 / NM_182961.4; = p.S4866R on NM_033071.3) | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780093837, COSV99556097; called by muse, mutect2, varscan2
- SYNJ2 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV62898841; called by muse, mutect2, varscan2
- TAFA2 | c.11G>T p.R4I | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as COSV101354051, COSV69183245; called by muse, mutect2, varscan2
- TANC2 | c.2878C>G p.L960V | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV101267277; called by muse, mutect2, varscan2
- TCEAL2 | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV100216246; called by muse, mutect2, varscan2
- TGIF2LX | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs773693755, COSV99383199; called by muse, mutect2, varscan2
- TUBB2B | c.1205G>C p.G402A | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99455313; called by muse, varscan2
- WNK3 | c.4802A>T p.Q1601L | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100670932; called by muse, mutect2, varscan2
- ZNF417 | c.1090A>T p.K364* | Nonsense Mutation (SNP) | VAF 93/171 reads (54%) | catalogued as COSV100364120; called by muse, mutect2, varscan2
- ZNF559 | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 82/191 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as rs749986545, COSV57835004; called by muse, mutect2, varscan2
- ABCC6 | c.2758G>T p.A920S | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.013); called by muse, mutect2
- DHRS7 | c.282C>A p.C94* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | called by muse, mutect2
- H2AX | c.245del p.R82Pfs*20 | Frame Shift Del (DEL) | VAF 51/171 reads (30%) | called by mutect2, pindel, varscan2
- IGHG2 | c.633C>G p.I211M | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.302); called by muse, mutect2
- KIAA1217 | c.1662dup p.K555Qfs*29 | Frame Shift Ins (INS) | VAF 25/42 reads (60%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.577G>C p.G193R | Missense Mutation (SNP) | VAF 120/606 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PABPC3 | c.950T>C p.F317S | Missense Mutation (SNP) | VAF 88/435 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- SLC20A1 | c.1684dup p.I562Nfs*37 | Frame Shift Ins (INS) | VAF 89/243 reads (37%) | called by mutect2, pindel, varscan2
- TP53 | c.917_919+14delinsAG p.X306_splice | Splice Site (DEL) | VAF 33/65 reads (51%) | called by pindel, varscan2*
- WSCD1 | c.1207_1218del p.R403_I406del | In Frame Del (DEL) | VAF 29/62 reads (47%) | called by pindel, varscan2
- ADAM12 | c.273C>A p.A91= | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV100900125; called by muse, varscan2
- CACNA1C | c.1026C>A p.G342= | Silent (SNP) | VAF 85/254 reads (33%) | catalogued as COSV100216479; called by muse, mutect2, varscan2
- CLVS2 | c.235C>A p.R79= | Silent (SNP) | VAF 60/157 reads (38%) | catalogued as COSV51563350, COSV99252287; called by muse, mutect2, varscan2
- DAB1 | c.639C>A p.P213= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV100139649, COSV59730631; called by muse, mutect2, varscan2
- DLGAP2 | c.273G>A p.P91= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as rs1343642805, COSV70099644; called by muse, mutect2, varscan2
- FASN | c.2799G>A p.L933= | Silent (SNP) | VAF 37/114 reads (32%) | catalogued as COSV100147469; called by muse, mutect2, varscan2
- HEPH | c.2340A>G p.R780= (on ENST00000343002; = p.R513= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/38 reads (76%) | catalogued as COSV100294301; called by muse, mutect2, varscan2
- INO80B | c.966C>T p.C322= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs755184376, COSV99270355; called by muse, mutect2, varscan2
- IQCN | c.3003C>T p.P1001= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as rs575963036, COSV62746916; called by muse, mutect2, varscan2
- LARP1B | c.525T>C p.G175= | Silent (SNP) | VAF 31/46 reads (67%) | catalogued as COSV99217886; called by muse, mutect2, varscan2
- MAP1A | c.5262C>T p.D1754= | Silent (SNP) | VAF 63/161 reads (39%) | catalogued as COSV100288236; called by muse, mutect2, varscan2
- MSR1 | c.339C>G p.V113= | Silent (SNP) | VAF 75/133 reads (56%) | catalogued as COSV100026430, COSV100026743; called by muse, mutect2, varscan2
- MYO7B | c.2034G>A p.S678= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs370974785; called by muse, varscan2
- NDST4 | c.1230A>T p.G410= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as COSV99995752; called by muse, mutect2, varscan2
- OGDH | c.2196C>T p.F732= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as rs749269578, COSV56050301; called by muse, mutect2, varscan2
- PCDHA4 | c.1302G>A p.S434= | Silent (SNP) | VAF 79/134 reads (59%) | catalogued as COSV100793217; called by muse, mutect2, varscan2
- PRKD1 | c.2715C>T p.L905= | Silent (SNP) | VAF 46/59 reads (78%) | catalogued as rs944749035, COSV59591930; called by muse, mutect2, varscan2
- RIC8B | c.888C>T p.L296= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as rs1237574685, COSV100822471; called by muse, mutect2, varscan2
- RNF19A | c.258C>T p.G86= | Silent (SNP) | VAF 71/214 reads (33%) | catalogued as rs746481923, COSV100347399; called by muse, mutect2, varscan2
- SLC26A7 | c.1797C>G p.G599= | Silent (SNP) | VAF 65/201 reads (32%) | catalogued as COSV99402813; called by muse, mutect2, varscan2
- SLC6A11 | c.1356C>T p.L452= | Silent (SNP) | VAF 89/156 reads (57%) | catalogued as rs758525371, COSV54391626; called by muse, mutect2, varscan2
- SLC7A9 | c.426G>A p.V142= | Silent (SNP) | VAF 34/54 reads (63%) | catalogued as rs750142742, COSV99195223; called by muse, mutect2
- SLITRK6 | c.1269G>T p.L423= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as COSV101233190; called by muse, mutect2
- SOCS2 | c.465G>A p.P155= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs768242857, COSV61391884; called by muse, mutect2, varscan2
- SPIRE1 | c.1122A>G p.L374= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV100563428; called by muse, mutect2, varscan2
- ZNF503 | c.219A>C p.P73= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as COSV65307729; called by muse, mutect2
- ZNF532 | c.1044G>A p.P348= | Silent (SNP) | VAF 56/83 reads (67%) | catalogued as rs777310864, COSV60172606; called by muse, mutect2, varscan2
- ZNF830 | c.1062G>A p.E354= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV100030484; called by muse, mutect2, varscan2
- LINC00482 | n.771C>T | RNA (SNP) | VAF 6/22 reads (27%) | called by muse, varscan2
- MIR1270 | chr19:20397537 G>A | 3'Flank (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- TTN | c.10360+5485A>G | Intron (SNP) | VAF 52/179 reads (29%) | catalogued as COSV60193632; called by muse, mutect2, varscan2
